Gene-level copy-number profile of tumor specimen TCGA-18-3419-01A from TCGA case TCGA-18-3419, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.4 years (26,813 days).
Specimen TCGA-18-3419-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.7f819acf-26df-470f-b528-019bca741cbd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-18-3419-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a1e66fec-51a4-4e1f-a60d-8bed64ed0ce2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 82; copy number 1: 12,351; copy number 2: 37,916; copy number 3: 6,958; copy number 4: 2,173; copy number 5: 239; copy number 15: 11; copy number 17: 47; copy number 27: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-18-3419-01): tumor purity 0.57, ploidy 2.02, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): 74 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:89,991,831–96,053,482, 70 genes (broad region; genes not listed).
- chr13:96,169,545–96,169,847, 1 gene: RN7SL164P.
- chr13:98,142,562–98,455,176, 1 gene (within-gene range 0–1): FARP1.
- chr13:98,329,655–98,435,840, 2 genes: AL161896.1, FARP1-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 333 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:38,276,178–38,523,180, 5 genes, copy number 5 (within-gene range 2–5): AC098680.2, AC098680.1, LINC02513, AC024023.1, LINC01258.
- chr8:38,269,704–38,560,939, 11 genes, copy number 15 (within-gene range 1–15): NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1.
- chr8:98,189,826–98,294,393, 1 gene, copy number 5 (within-gene range 3–5): NIPAL2.
- chr8:98,391,401–98,391,514, 1 gene, copy number 5: AP003355.3.
- chr19:55,039,108–56,217,777, 83 genes, copy number 17–27 (within-gene range 2–27) (broad region; genes not listed).
- chr20:43,894,720–51,131,667, 232 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9,973. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
